Gene-level copy-number profile of tumor specimen TCGA-MA-AA3Z-01A from TCGA case TCGA-MA-AA3Z, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Cervix uteri; FIGO stage: Stage IB2; Tumor grade: GX; Age at diagnosis: 43.2 years (15,762 days).
Specimen TCGA-MA-AA3Z-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-CESC.3eeef706-d692-4d89-a81c-6d24dc8853a6.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-MA-AA3Z-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 806 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/ddbfe0ae-d544-4e69-939a-57e51c455f3b

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 2; copy number 1: 5,477; copy number 2: 51,837; copy number 3: 1,125; copy number 4: 595; copy number 5: 771; copy number 17: 10.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-MA-AA3Z-01A-11D-A386-01): tumor purity 0.76, ploidy 2, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 2 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr20:15,021,553–15,022,958, 2 genes: RNU6-1159P, RNU6-115P.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 747 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:156,523,740–198,222,513, 737 genes, copy number 5 (broad region; genes not listed).
- chr4:43,388,157–44,025,516, 10 genes, copy number 17: AC098590.2, AC098590.1, LINC02383, AC114774.1, RN7SL691P, AC080132.1, RN7SL193P, NDUFB4P12, AC114757.1, LINC02475.

Autosomal genes at a single copy (total copy number 1): 5,476. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
